Gene-level copy-number profile of tumor specimen C3N-00822-01 from CPTAC case C3N-00822, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.5 years (19,536 days).
Specimen C3N-00822-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34fe63d3-0733-40a1-a10c-dc8353f13d84.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00822-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/17156905-d4b6-4322-9340-0adb01528b43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 18,087; copy number 2: 34,041; copy number 3: 4,354; copy number 4: 1,081; copy number 5: 690; copy number 6: 29; copy number 7: 36; copy number 12: 28.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,726,636–62,726,740, 1 gene (within-gene range 0–2): Y_RNA.
- chr2:140,231,423–142,131,016, 8 genes (within-gene range 0–2): LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr3:78,597,239–79,767,998, 5 genes (within-gene range 0–1): ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923.
- chr4:88,523,810–88,730,103, 10 genes (within-gene range 0–1): AC098582.1, PIGY-DT, AC083829.1, RN7SKP244, HERC3, RNU6-33P, NAP1L5, FAM13A-AS1, AC108065.2, AC108065.1.
- chr5:59,039,761–59,314,800, 2 genes (within-gene range 0–2): AC092343.1, AC008833.1.
- chr6:93,240,020–93,677,954, 2 genes: EPHA7, AL591519.1.
- chr7:141,704,003–141,738,346, 3 genes (within-gene range 0–1): WEE2-AS1, WEE2, RNU1-82P.
- chr7:152,120,001–152,129,686, 2 genes (within-gene range 0–1): AC006017.1, YBX1P4.
- chr8:4,787,332–4,788,584, 1 gene (within-gene range 0–1): PAICSP4.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:60,914,407–60,964,196, 5 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:83,242,990–83,713,378, 7 genes (within-gene range 0–2): FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1.
- chr11:12,303,533–12,308,216, 1 gene: AC025300.1.
- chr11:122,099,757–122,099,844, 1 gene (within-gene range 0–1): MIR125B1.
- chr11:122,146,522–122,152,308, 2 genes: MIRLET7A2, MIR100.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 783 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:142,157,527–174,378,005, 466 genes, copy number 5 (broad region; genes not listed).
- chr3:188,941,715–198,123,232, 209 genes, copy number 5 (broad region; genes not listed).
- chr4:68,509,441–68,517,647, 1 gene, copy number 5: UGT2B29P.
- chr8:38,099,471–39,580,134, 42 genes, copy number 7–12: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr9:106,974,833–107,102,988, 1 gene, copy number 6 (within-gene range 2–6): AL807761.4.
- chr9:107,918,866–108,254,820, 5 genes, copy number 5: RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1.
- chr9:111,327,483–111,631,289, 7 genes, copy number 5: OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P.
- chr9:120,600,811–120,721,972, 2 genes, copy number 5: MEGF9, AHCYP2.
- chr11:70,078,302–70,436,584, 14 genes, copy number 7: ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr16:7,726,841–9,121,635, 28 genes, copy number 6 (within-gene range 4–6): AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1.
- chr20:22,547,671–22,966,063, 8 genes, copy number 7: LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1.

Autosomal genes at a single copy (total copy number 1): 16,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
